TARGET case TARGET-15-SJMPAL040036 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/538662d9-310a-4de4-bda9-5793162b40fb

Demographics
Sex at birth: female; Age at index: 5 years.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 5.4 years (1,983 days); Year of diagnosis: 2013.

Follow-up (1 entry)
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 379 ×10³/µL.

Biospecimens (7 samples)
- Samples TARGET-15-SJMPAL040036-03A, TARGET-15-SJMPAL040036-03A.1, TARGET-15-SJMPAL040036-03A.2, TARGET-15-SJMPAL040036-03A.3, TARGET-15-SJMPAL040036-03A.4, TARGET-15-SJMPAL040036-03B (6 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-15-SJMPAL040036-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Protocol: AIEOP
- WBC at Diagnosis: 378.8
- Initial Therapy: ALL
- WHO ALAL Classification: T/M
- WHO Dx: T/M
